Somatic mutation profile of tumor specimen TCGA-DH-A66F-01A (aliquot TCGA-DH-A66F-01A-11D-A29Q-08) from TCGA case TCGA-DH-A66F, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 49.8 years (18,193 days).
Specimen TCGA-DH-A66F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e41b3fc-4af5-487c-9553-3b3a17a05534.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DH-A66F-10A (Blood Derived Normal), aliquot TCGA-DH-A66F-10A-01D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c78917d4-8850-478b-86d6-cf4f12973827

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3, Nonsense Mutation 2, Frame Shift Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 21/54 reads (39%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ARID1B | c.3076C>T p.Q1026* | Nonsense Mutation (SNP) | VAF 9/72 reads (13%) | catalogued as rs1554229940, COSV51672051; called by muse, mutect2, varscan2
- DNMBP | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV60629636; called by muse, mutect2, varscan2
- HPS5 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772160206, COSV56378344; called by muse, mutect2, varscan2
- ITIH3 | c.2033G>A p.R678H | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.255); catalogued as rs747148462, COSV69648464; called by muse, mutect2, varscan2
- KIR2DL1 | c.334T>A p.S112T | Missense Mutation (SNP) | VAF 96/555 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52411793, COSV52412865; called by muse, mutect2, varscan2
- PLEKHG6 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs373302901; called by muse, mutect2, varscan2
- SLC23A1 | c.1478T>C p.L493P | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV62297172; called by muse, mutect2, varscan2
- SLC6A2 | c.1778C>T p.T593M | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs758951794, COSV54920133; called by muse, mutect2, varscan2
- TRPV2 | c.181C>T p.R61* | Nonsense Mutation (SNP) | VAF 16/59 reads (27%) | catalogued as rs373733043; called by muse, mutect2, varscan2
- UNC13A | c.2624A>G p.Y875C | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV53203122; called by muse, mutect2, varscan2
- UNC13D | c.1441G>A p.V481M | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.694); catalogued as COSV52886146; called by mutect2, varscan2
- YME1L1 | c.956G>A p.R319Q (on ENST00000326799 / NM_139312.3; = p.R262Q on NM_014263.4) | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.389); catalogued as rs749405954, COSV58760025; called by muse, mutect2, varscan2
- ZNF335 | c.3378C>G p.H1126Q | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV59819101; called by muse, mutect2
- ASCC1 | c.167del p.P56Hfs*8 | Frame Shift Del (DEL) | VAF 17/65 reads (26%) | called by mutect2, pindel, varscan2
- COL15A1 | c.4035G>A p.A1345= | Silent (SNP) | VAF 72/195 reads (37%) | catalogued as rs929599493, COSV66645279; called by muse, mutect2, varscan2
- FOXS1 | c.672C>T p.F224= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as COSV54067428, COSV99639739; called by muse, mutect2
- SYNJ1 | c.2172C>T p.F724= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs765857459, COSV59144937; called by muse, mutect2, varscan2
